TCGA case TCGA-G4-6309 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4be17c8-0855-432c-bb80-28bb24b62f32

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 40.3 years (14,729 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,600 days (7.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 24; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Days to treatment start: 73 days; Days to treatment end: 254 days; Number of cycles: 8; Treatment dose: 355,600 mg; Prescribed dose: 3600; Prescribed dose units: mg/day; Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 46.3 years (16,905 days); Days to diagnosis: 2,176 days (6.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 1,386 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,574 days (4.3 years); Disease response: Tumor Free.
- Day 2,176 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 2,176 days (6.0 years).
- Days to follow up: 2,600 days (7.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Loss of Expression.
- Microsatellite Instability: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65.4 kg; Height: 176 cm; BMI: 21.1.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6309-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.7; Shortest dimension: 0.1.
  Slide TCGA-G4-6309-01A-01-BS1: Section location: Top; Percent tumor cells: 77; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-G4-6309-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6309-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Height cm at diagnosis: 176 cm; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Xeloda.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,600 days; disease-specific survival: no event (censored), 2,600 days; disease-free interval: event (new tumor event after initially disease-free), 2,176 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,176 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G4-6309-01A-21D-1834-01): tumor purity 0.81, ploidy 2, whole-genome doublings 0.
